HCMI case HCM-CSHL-0153-C50 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ad400773-3306-4e97-bda6-f03fcc471692

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Year of birth: 1955; Vital status: Alive.

Diagnoses (1)
1. Lobular carcinoma, NOS: ICD-O-3 morphology code: 8520/3; ICD-10 code: C50.912; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Classification of tumor: primary; Age at diagnosis: 62.7 years (22,886 days); AJCC staging edition: 8th; AJCC clinical stage: Stage IIA; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Prior malignancy: no; Prior treatment: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 53 days.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment end: 165 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease.

Follow-up (2 entries)
- Days to follow up: 641 days (1.8 years); Disease response: Stable Disease; Progression or recurrence: No.
- Follow-up contacts recording only the day: day 0, day 181.

Molecular and laboratory tests
- ERBB2 (IHC): Negative.
- ESR1 (IHC): 8; Specialized molecular test: Allred score.
- PGR (IHC): Positive.
- Test (Other): Low; Specialized molecular test: Oncotype.

Other clinical attributes
- Day 0: Menopause status: Postmenopausal.
- Timepoint category: Initial Diagnosis; Weight: 104.32 kg; Height: 165.1 cm; BMI: 38.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Breast Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0153-C50-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide HCM-CSHL-0153-C50-01B-01-S2-HE: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 50; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-CSHL-0153-C50-01B-02-S1-HE: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 4; Percent necrosis: 0; Percent stromal cells: 16; Percent lymphocyte infiltration: 6; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 3.
- Sample HCM-CSHL-0153-C50-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-CSHL-0153-C50-85E: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
